Gene-level copy-number profile of tumor specimen TCGA-HZ-8637-01A from TCGA case TCGA-HZ-8637, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 76.5 years (27,929 days).
Specimen TCGA-HZ-8637-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.f67b8e43-8a35-49ac-a8fa-9ebf57f22831.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HZ-8637-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7567ed8f-642a-48e5-94de-0520a738d589

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,966; copy number 2: 37,970; copy number 3: 17,039; copy number 4: 2,758; copy number 6: 28; copy number 11: 59.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HZ-8637-01A-11D-2392-01): tumor purity 0.21, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 67 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:64,275,257–64,611,888, 10 genes, copy number 11: TECRL, RNU6-191P, DPP3P1, MTCO3P27, MTCYBP16, MTND6P16, MTND5P13, MTND4LP31, MTND3P24, MTCO3P28.
- chr10:100,912,963–102,382,899, 49 genes, copy number 11 (within-gene range 2–11): SLF2, AL133215.3, MRPL43, SEMA4G, MIR608, AL133215.1, TWNK, LZTS2, PDZD7, SFXN3, AL133215.2, KAZALD1, TLX1NB, TLX1, LINC01514, SMARCE1P7, LBX1, LBX1-AS1, LINC02681, RNU2-43P, AL133387.1, AL133387.2, BTRC, RNU2-59P, DPCD, POLL, MIR3158-1, MIR3158-2, FBXW4, RNU6-1165P, AC010789.2, AC010789.1, FGF8, NPM3, OGA, KCNIP2-AS1, KCNIP2, ARMH3, Metazoa_SRP, Y_RNA, HPS6, AL500527.1, AL500527.2, LDB1, PPRC1, NOLC1, ELOVL3, PITX3, GBF1.
- chr11:130,771,413–131,215,163, 8 genes, copy number 6: AP003486.2, PPP1R10P1, LINC02551, SNX19, AP003486.1, RN7SL167P, AP002856.3, AP002856.1.

Autosomal genes at a single copy (total copy number 1): 1,966. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
